Somatic mutation profile of tumor specimen TCGA-HZ-A4BH-01A (aliquot TCGA-HZ-A4BH-01A-11D-A26I-08) from TCGA case TCGA-HZ-A4BH, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 75.7 years (27,637 days).
Specimen TCGA-HZ-A4BH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1fec4e3-631a-4149-adf9-b9077c9715c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A4BH-10A (Blood Derived Normal), aliquot TCGA-HZ-A4BH-10A-01D-A26I-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34b5383e-9a45-4374-ab12-f6ab749676dd

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 48, Silent 16, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 17/131 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GABRG2 | c.1088G>A p.R363Q (on ENST00000361925 / NM_001375343.1; = p.R323Q on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/495 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs397514737, CM1314732, COSV62717474; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 23/130 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 39/236 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGAP2 | c.1474C>T p.R492C (on ENST00000547588 / NM_001122772.2; = p.R156C on NM_014770.4) | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as rs1312087058, COSV57730265, COSV57733140; called by muse, mutect2
- ANKRD30A | c.3232A>G p.I1078V (on ENST00000611781; = p.I1022V on NM_052997.2) | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100654030; called by muse, mutect2, varscan2
- APBA2 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 133/941 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.797); catalogued as rs140795962; called by muse, mutect2, varscan2
- AXIN1 | c.1961C>T p.S654L | Missense Mutation (SNP) | VAF 46/622 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs377025983; called by muse, mutect2
- CCDC116 | c.1759G>T p.D587Y | Missense Mutation (SNP) | VAF 34/468 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV99489415; called by muse, mutect2
- CHAT | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs146236256; called by muse, mutect2, varscan2
- CHML | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 34/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59365507; called by muse, mutect2
- CKMT2 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 29/429 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV99562441; called by muse, mutect2
- CLTCL1 | c.3892G>A p.E1298K | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV99595465; called by muse, mutect2
- DEFB136 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 91/1256 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as rs762547832, COSV66364055; called by muse, mutect2
- DISC1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 30/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs139420445; called by muse, mutect2
- DYSF | c.615T>A p.S205R | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as rs1309219943, COSV99249022; called by muse, mutect2
- EYS | c.1395C>G p.F465L | Missense Mutation (SNP) | VAF 73/543 reads (13%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100676835; called by muse, mutect2, varscan2
- FRMPD3 | c.4261T>C p.Y1421H | Missense Mutation (SNP) | VAF 90/325 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99346720; called by muse, mutect2, varscan2
- GJB4 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs561459140, COSV58355721; called by muse, mutect2, varscan2
- GPR15 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 46/710 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.053); catalogued as COSV52520005, COSV99423881; called by muse, mutect2
- GRAMD1A | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 55/830 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758428360, COSV58768950; called by muse, mutect2
- GRID1 | c.2690C>T p.S897L | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs779461467, COSV60055756; called by muse, mutect2, varscan2
- IL1RN | c.103A>T p.M35L (on ENST00000409930 / NM_173842.3; = p.M17L on NM_000577.5) | Missense Mutation (SNP) | VAF 40/364 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99381741; called by muse, mutect2, varscan2
- KCNN1 | c.1099C>T p.R367W | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1298141614, COSV99716163; called by muse, mutect2, varscan2
- MAP2K7 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 57/217 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV67608070; called by muse, mutect2, varscan2
- MROH5 | c.3623C>T p.T1208M | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as rs778801891, COSV100267361; called by muse, mutect2, varscan2
- MSRB3 | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 90/622 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267603630, COSV57589447; called by muse, mutect2, varscan2
- MTG2 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 77/301 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs759664974, COSV63695560; called by muse, mutect2, varscan2
- NPAP1 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 57/417 reads (14%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.519); catalogued as COSV100275712; called by muse, mutect2, varscan2
- NRXN2 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 83/597 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs1238286270, COSV55446744; called by muse, mutect2, varscan2
- NTNG1 | c.1361C>T p.P454L | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1009840067, COSV100903705; called by muse, mutect2, varscan2
- OR1A1 | c.755G>A p.G252D | Missense Mutation (SNP) | VAF 137/789 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767431213, COSV100410800, COSV58404504; called by muse, mutect2, varscan2
- PCDH12 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 52/306 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as rs550140086, COSV51524306; called by muse, mutect2, varscan2
- PCDHA3 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 62/1077 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV65366607; called by muse, mutect2
- PEAK1 | c.1350A>G p.I450M | Missense Mutation (SNP) | VAF 175/1096 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.87); catalogued as COSV100433268; called by muse, mutect2, varscan2
- PLAAT4 | c.52C>T p.R18C | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs770983321, COSV55373787; called by muse, mutect2
- PRAMEF4 | c.148C>T p.R50C | Missense Mutation (SNP) | VAF 68/900 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs753866096, COSV52438989; called by muse, mutect2
- PRL | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 46/405 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs569915370, COSV60593021; called by muse, mutect2, varscan2
- PRODH2 | c.794A>T p.E265V (on ENST00000301175; = p.E189V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/301 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV99995394; called by muse, mutect2
- PRODH2 | c.659G>T p.G220V (on ENST00000301175; = p.G144V on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/460 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1365721145, COSV99995397; called by muse, mutect2
- RSU1 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 62/822 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.917); catalogued as rs750770290, COSV61715024; called by muse, mutect2
- RYBP | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 47/288 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as COSV101523312, COSV72181223; called by muse, mutect2, varscan2
- SKP2 | c.748A>G p.T250A | Missense Mutation (SNP) | VAF 26/496 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV99948203; called by muse, mutect2
- SLC16A10 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 47/467 reads (10%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.76); catalogued as COSV100920933; called by muse, mutect2, varscan2
- TOGARAM1 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 54/984 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); catalogued as COSV100753192; called by muse, mutect2
- WDR47 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100728392; called by muse, mutect2
- ZNF267 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100339864, COSV56251602; called by muse, mutect2
- ZNF658 | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs1370452460; called by mutect2, varscan2
- ABI2 | c.1162_1165del p.N388Efs*105 (on ENST00000295851 / NM_001375719.1; = p.N321Efs*22 on NM_005759.7 and 35 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 72/531 reads (14%) | called by mutect2, pindel, varscan2
- ABHD15 | c.1143C>T p.F381= | Silent (SNP) | VAF 36/502 reads (7%) | catalogued as COSV100213017; called by muse, mutect2
- CCDC61 | c.201C>T p.F67= | Silent (SNP) | VAF 39/205 reads (19%) | catalogued as COSV99625589; called by muse, mutect2, varscan2
- COL5A3 | c.2319C>T p.G773= | Silent (SNP) | VAF 25/273 reads (9%) | catalogued as rs756535935, COSV53407745; called by muse, mutect2, varscan2
- FRMPD2 | c.186C>T p.A62= | Silent (SNP) | VAF 44/232 reads (19%) | catalogued as COSV100564008; called by muse, mutect2, varscan2
- KCNJ4 | c.798C>T p.D266= | Silent (SNP) | VAF 23/287 reads (8%) | catalogued as rs769582370, COSV57858235; called by muse, mutect2
- KDM5B | c.2316G>A p.K772= | Silent (SNP) | VAF 77/982 reads (8%) | catalogued as COSV99351017; called by muse, mutect2
- MYLK | c.3900G>A p.A1300= | Silent (SNP) | VAF 118/1544 reads (8%) | catalogued as rs563116446, COSV60613110; ClinVar: uncertain significance; called by muse, mutect2
- NBEAL1 | c.5208C>T p.L1736= | Silent (SNP) | VAF 23/429 reads (5%) | catalogued as COSV71374548; called by muse, mutect2
- OR1D2 | c.186C>T p.F62= | Silent (SNP) | VAF 91/990 reads (9%) | catalogued as COSV58921008; called by muse, mutect2
- PCDH18 | c.2016G>A p.L672= | Silent (SNP) | VAF 86/1016 reads (8%) | catalogued as COSV61273345; called by muse, mutect2
- PLD3 | c.1083C>T p.R361= | Silent (SNP) | VAF 80/412 reads (19%) | catalogued as COSV99396381; called by muse, mutect2, varscan2
- POTEE | c.2199C>T p.S733= | Silent (SNP) | VAF 44/473 reads (9%) | catalogued as rs1158474060; called by muse, mutect2
- RESF1 | c.1764T>C p.L588= | Silent (SNP) | VAF 84/558 reads (15%) | catalogued as COSV100440462; called by muse, mutect2, varscan2
- SAXO1 | c.312G>A p.T104= | Silent (SNP) | VAF 108/534 reads (20%) | catalogued as rs112030642, COSV101000162; called by muse, mutect2, varscan2
- SEPSECS | c.294C>T p.S98= | Silent (SNP) | VAF 80/475 reads (17%) | catalogued as rs377253617; ClinVar: likely benign; called by muse, mutect2, varscan2
- TPO | c.2577C>T p.I859= | Silent (SNP) | VAF 30/288 reads (10%) | catalogued as rs760976450, COSV61096756, COSV61097630; called by muse, mutect2
